Somatic mutation profile of tumor specimen TCGA-KO-8406-01A (aliquot TCGA-KO-8406-01A-11D-2310-10) from TCGA case TCGA-KO-8406, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 17.9 years (6,556 days).
Specimen TCGA-KO-8406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df02eb49-4500-4c21-8e5f-64b95f78621d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8406-11A (Solid Tissue Normal), aliquot TCGA-KO-8406-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bec585e-f22c-4e18-912d-3dd112f2d485

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLC2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs757724338; called by muse, mutect2, varscan2
- MDN1 | c.16775C>A p.A5592D | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101020658; called by muse, mutect2
- PCDHA9 | c.813A>C p.E271D | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.17); catalogued as rs1224094157; called by muse, mutect2, varscan2
- PDCD2L | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs910600872; called by muse, mutect2, varscan2
- PZP | c.2768G>T p.S923I | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV99735546; called by muse, mutect2
- PPP1R2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ECT2L | c.498G>A p.T166= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1023153608, COSV62886705; called by muse, mutect2
- C3P1 | n.3077G>A | RNA (SNP) | VAF 20/229 reads (9%) | catalogued as rs563514269; called by muse, mutect2
